Somatic mutation profile of tumor specimen 0DQSTW from CCDI case PBCFLK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.6 years (4,961 days).
Specimen 0DQSTW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6ca4487-88c3-4019-9a2e-f49036ae2b91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQSUQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e31a7e8-bf3c-4660-9af4-83955d1b0176

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STT3B | c.1605A>G p.I535M | Missense Mutation (SNP) | VAF 200/430 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.409); catalogued as rs771309912; called by muse, mutect2, varscan2
- USP54 | c.2697C>G p.L899= | Silent (SNP) | VAF 86/586 reads (15%) | called by muse, mutect2, varscan2
- CBWD3 | c.707+16T>A | Intron (SNP) | VAF 51/573 reads (9%) | called by muse, mutect2, varscan2
- ETV1 | c.181+365_181+371del | Intron (DEL) | VAF 66/123 reads (54%) | called by mutect2, pindel, varscan2
- ZNF704 | c.*27G>T | 3'UTR (SNP) | VAF 53/294 reads (18%) | called by muse, mutect2, varscan2
